Gene-level copy-number profile of tumor specimen ALCH-B1Y9-TTP1-A from ALCHEMIST case ALCH-B1Y9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.2 years (24,164 days).
Specimen ALCH-B1Y9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ed0c779d-9b59-4e2d-b34e-9c50113c417e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1Y9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/1de1cd49-612d-44a7-8336-97ffab3ae312

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 5,589; copy number 2: 47,099; copy number 3: 4,942; copy number 4: 865; copy number 5: 149; copy number 6: 165; copy number 10: 52; copy number 12: 12; copy number 17: 1; copy number 57: 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:56,805,336–56,808,148, 1 gene: CICP28.
- chr9:136,483,495–136,546,048, 4 genes (within-gene range 0–2): C9orf163, NOTCH1, MIR4673, AL592301.1.
- chr10:46,888–74,163, 1 gene: TUBB8.
- chr12:131,894,622–131,929,351, 3 genes (within-gene range 0–3): ULK1, AC131009.4, AC131009.1.
- chr14:103,519,667–103,537,073, 3 genes: CKB, AL133367.1, TRMT61A.
- chr16:2,223,580–2,238,711, 3 genes: E4F1, AC009065.1, DNASE1L2.
- chr19:1,578,339–1,652,615, 4 genes (within-gene range 0–1): AC005943.1, UQCR11, TCF3, RNU6-1223P.
- chr21:44,989,864–44,995,185, 2 genes: LINC00163, LINC00165.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 380 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–147,003,618, 114 genes, copy number 6 (broad region; genes not listed).
- chr1:147,541,501–149,936,879, 99 genes, copy number 5 (broad region; genes not listed).
- chr3:168,008,689–172,831,229, 93 genes, copy number 5–12 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 5: TRGC2.
- chr7:38,257,879–38,340,998, 14 genes, copy number 5: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes, copy number 5 (within-gene range 2–5): TRGV5P, TRGV5.
- chr8:124,301,315–124,372,692, 2 genes, copy number 6: AC090192.1, TMEM65.
- chr14:22,066,016–22,486,296, 48 genes, copy number 6: AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52.
- chr14:22,547,506–22,552,156, 1 gene, copy number 6: TRAC.
- chr16:2,644,084–2,682,379, 2 genes, copy number 5–17: AC141586.2, ERVK13-1.
- chr21:43,414,483–43,427,131, 1 gene, copy number 57: SIK1.
- chr22:20,314,238–20,321,203, 3 genes, copy number 5: DGCR6L, AC007663.4, AC007663.3.

Autosomal genes at a single copy (total copy number 1): 2,752. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
